Gene-level copy-number profile of tumor specimen TCGA-T3-A92N-01A from TCGA case TCGA-T3-A92N, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 79.1 years (28,879 days).
Specimen TCGA-T3-A92N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.78a40b93-fc81-4439-a5ed-149639e0f2a1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-T3-A92N-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8afaeb39-a497-4886-a664-04fb9e2d3816

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,093; copy number 2: 21,327; copy number 3: 23,582; copy number 4: 6,479; copy number 5: 4,659; copy number 6: 1,255; copy number 7: 60; copy number 8: 20; copy number 9: 186; copy number 10: 5; copy number 13: 13; copy number 17: 141.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-T3-A92N-01A-11D-A390-01): tumor purity 0.67, ploidy 2.97, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 425 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:24,816,331–26,212,532, 20 genes, copy number 8: AL157385.2, PRTFDC1, AL157385.1, RN7SKP241, AL512598.2, AL512598.1, ENKUR, THNSL1, LINC01516, GPR158-AS1, GPR158, AL354976.1, RN7SKP220, GPN3P1, LINC00836, HIRAP1, RNA5SP306, RNU6-632P, AL358612.1, MYO3A.
- chr14:26,208,036–52,791,668, 403 genes, copy number 7–17 (broad region; genes not listed).
- chr14:52,792,875–52,820,034, 2 genes, copy number 7: AL139317.1, AL139317.2.

Autosomal genes at a single copy (total copy number 1): 1,042. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
